Gene-level copy-number profile of tumor specimen TCGA-BR-7717-01A from TCGA case TCGA-BR-7717, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 63.2 years (23,102 days).
Specimen TCGA-BR-7717-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.39f766b8-95f8-4428-ac63-a52903fe389e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-7717-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1c6e5ecc-f020-4d9d-8419-141e82ddc864

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,270; copy number 3: 4,047; copy number 4: 29,808; copy number 5: 2,161; copy number 6: 13,181; copy number 7: 1,885; copy number 8: 4,749; copy number 9: 409; copy number 10: 675; copy number 11: 853; copy number 12: 22; copy number 14: 220; copy number 15: 84; copy number 18: 99; copy number 20: 120; copy number 24: 91; copy number 26: 1; copy number 40: 69; copy number 43: 13; copy number 46: 1; copy number 50: 13; copy number 67: 1; copy number 99: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-7717-01A-11D-2052-01): tumor purity 0.55, ploidy 2.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,713 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:65,319,563–67,701,155, 22 genes, copy number 12–67 (within-gene range 3–67): EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3, RNU6-699P, AC104806.2, RNU1-63P, RNA5SP527, AC104806.1, CENPC, STAP1, AC096720.2, UBA6, AC096720.1.
- chr4:67,716,375–67,884,002, 7 genes, copy number 12: ST3GAL1P1, AC079880.1, AC079880.2, GNRHR, SNORA62, TMPRSS11CP, TMPRSS11D.
- chr4:156,634,494–171,298,267, 179 genes, copy number 11 (broad region; genes not listed).
- chr5:58,198–3,601,403, 92 genes, copy number 9 (broad region; genes not listed).
- chr6:94,446,740–108,526,796, 147 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).
- chr6:133,987,581–156,774,662, 366 genes, copy number 10–20 (broad region; genes not listed).
- chr6:156,776,360–156,780,455, 3 genes, copy number 18: AL355297.3, MIR4466, AL355297.1.
- chr7:53,926,676–55,862,755, 42 genes, copy number 99: LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3.
- chr8:7,028,641–8,226,614, 92 genes, copy number 24–46 (broad region; genes not listed).
- chr8:10,764,961–12,333,693, 69 genes, copy number 40 (within-gene range 4–40) (broad region; genes not listed).
- chr8:43,219,960–43,378,510, 13 genes, copy number 50: VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3.
- chr9:26,642,697–43,045,120, 428 genes, copy number 10–26 (broad region; genes not listed).
- chr9:108,821,697–109,320,964, 13 genes, copy number 43 (within-gene range 5–43): RPL36AP35, AL359692.1, ACTL7B, ACTL7A, ELP1, ABITRAM, CTNNAL1, TMEM245, Y_RNA, MIR32, FRRS1L, EPB41L4B, RNU6-984P.
- chr10:44,712–1,737,525, 28 genes, copy number 10: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26, AL157709.1, LARP4B, AL359878.2, AL359878.1, GTPBP4, IDI2, IDI2-AS1, IDI1, WDR37, LINC00200, ADARB2, AL392083.2, AL392083.1, AL513304.1, ADARB2-AS1.
- chr10:3,991,160–6,879,450, 77 genes, copy number 10 (broad region; genes not listed).
- chr10:11,316,833–16,207,927, 92 genes, copy number 10 (broad region; genes not listed).
- chr11:66,312,853–69,926,813, 159 genes, copy number 14 (broad region; genes not listed).
- chr14:18,333,726–25,432,234, 479 genes, copy number 11 (broad region; genes not listed).
- chr14:52,111,122–63,543,377, 202 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr17:70,778,604–71,743,468, 7 genes, copy number 9: AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1.
- chr20:87,250–3,245,382, 108 genes, copy number 9 (broad region; genes not listed).
- chr20:52,192,159–55,744,938, 40 genes, copy number 15 (within-gene range 8–15): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1.
- chr20:57,488,392–59,259,113, 48 genes, copy number 11: HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
